Somatic mutation profile of tumor specimen MP2PRT-PASGCS-TMP1-A (aliquot MP2PRT-PASGCS-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASGCS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,380 days).
Specimen MP2PRT-PASGCS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f40c10e3-a0fd-4b3a-9a77-7dff0155045e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASGCS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASGCS-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13c0a981-8592-41df-b2ae-7b7962b07ddb

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 139/384 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as rs777148297; called by muse, mutect2, varscan2
- PCDH15 | c.1396C>T p.L466F | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV100217488, COSV57265915; called by muse, mutect2
- PRDM16 | c.1537G>A p.G513S | Missense Mutation (SNP) | VAF 306/880 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.072); catalogued as rs200278862, COSV54587509; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCAP31 | c.459G>A p.E153= | Silent (SNP) | VAF 25/385 reads (6%) | called by muse, mutect2
- EMC4 | c.*39C>G | 3'UTR (SNP) | VAF 19/460 reads (4%) | called by muse, mutect2
- PPP2R5C | c.93+2210A>G | Intron (SNP) | VAF 115/319 reads (36%) | called by muse, mutect2, varscan2
